Gene-level copy-number profile of tumor specimen HCM-SANG-0778-C25-01A-01D-A80T-32 from HCMI case HCM-SANG-0778-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0778-C25-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48106241-9462-497e-aa9d-bd21618998a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0778-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/a53dc25e-93e6-4887-a7c3-2355af96bb17

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 19; copy number 2: 23,114; copy number 3: 5,966; copy number 4: 21,945; copy number 5: 4,875; copy number 6: 1,845; copy number 7: 380; copy number 8: 45; copy number 9: 53; copy number 10: 27; copy number 11: 18.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:20,999,509–22,214,672, 55 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:41,890,314–42,714,539, 21 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–2): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 98 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,842,875–150,145,329, 17 genes, copy number 9 (within-gene range 4–9): H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45.
- chr7:2,403,588–2,664,802, 7 genes, copy number 10–11: CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3.
- chr7:15,841,297–15,842,360, 1 gene, copy number 9: AC006041.1.
- chr7:16,753,755–16,888,885, 6 genes, copy number 11: TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:16,938,225–16,938,557, 1 gene, copy number 11: AC098592.1.
- chr7:33,904,308–35,038,271, 12 genes, copy number 10: BMPER, AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N.
- chr7:50,839,363–51,022,990, 4 genes, copy number 11 (within-gene range 6–11): AC004920.1, AC009296.1, AC004830.2, AC004830.1.
- chr8:127,578,473–127,636,867, 1 gene, copy number 11: AC104370.1.
- chr8:140,657,900–141,518,737, 23 genes, copy number 9 (within-gene range 4–9): PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1.
- chr10:126,988,095–127,026,507, 2 genes, copy number 9 (within-gene range 6–9): AL359094.1, AL359094.2.
- chr12:98,317,741–98,645,113, 10 genes, copy number 9: AC008055.1, RNU4-41P, SLC9A7P1, LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53, IKBIP.
- chr13:72,727,749–73,661,891, 14 genes, copy number 10: BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
